Somatic mutation profile of tumor specimen HCM-WCMC-0751-C54-01A (aliquot HCM-WCMC-0751-C54-01A-01D-A87L-36) from HCMI case HCM-WCMC-0751-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, secretory variant; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 54.6 years (19,958 days).
Specimen HCM-WCMC-0751-C54-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98302032-4486-4f17-be33-9d68cda1603c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0751-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-0751-C54-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69d560da-84da-4807-8ba1-6f2374f1497d

The open-access MAF lists 20,147 somatic variants for this specimen: 14,383 protein-altering or splice-affecting, 5,058 silent, 706 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13,144, Silent 5,058, Nonsense Mutation 812, Intron 433, Splice Region 134, Frame Shift Del 114, Splice Site 93, 3'UTR 92, 5'Flank 61, Frame Shift Ins 58, 5'UTR 46, RNA 44.

Variants (750 of 20,147; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO2 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs752034900, CM1411483, COSV53442796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 78/316 reads (25%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARMC4 | c.2765G>A p.G922E | Missense Mutation (SNP) | VAF 89/395 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1564439559, COSV59470393; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 97/460 reads (21%) | catalogued as rs749036865, CM080076, COSV53731268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CA5A | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 29/228 reads (13%) | catalogued as rs767402215, COSV59239468; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs74551128, CM900045; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- CHRNA1 | c.697G>A p.V233M (on ENST00000261007 / NM_001039523.3; = p.V208M on NM_000079.4) | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); catalogued as rs199470445, CM117920, COSV53682929, COSV53685572; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHRNG | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912670, CM062516; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- COL4A3 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293137291, CM1413325; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- COQ2 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 46/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs121918233, CM077244; ClinVar: pathogenic; called by muse, mutect2
- CTCF | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs886039600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDC | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853207, CM984684; ClinVar: pathogenic; called by muse, varscan2
- DEPDC5 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 40/149 reads (27%) | catalogued as rs587777459, CM134018, COSV104383263; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHX30 | c.1478G>A p.R493H (on ENST00000445061 / NM_138615.3; = p.R454H on NM_014966.3) | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519436, COSV53140099; ClinVar: pathogenic; called by muse, varscan2
- DNAI1 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs794727103, CM066047; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EYS | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 132/555 reads (24%) | catalogued as rs1388177618; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F9 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs137852228, CM940432, CM950426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAM161A | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 60/352 reads (17%) | catalogued as rs777678022, CM142945; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FANCA | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs148473140, CM970486, COSV101224685; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs145942328, CM145706; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 61/377 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- FGD1 | c.26dup p.A10Rfs*104 | Frame Shift Ins (INS) | VAF 44/211 reads (21%) | catalogued as rs1557191602; ClinVar: likely pathogenic; called by mutect2, varscan2
- FOXP2 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 66/347 reads (19%) | catalogued as rs1178491246, COSV63493477; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FRMD7 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 82/397 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852212, CM074182, CM080375, COSV53745682, COSV53747620; ClinVar: pathogenic; called by muse, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 104/427 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- GCH1 | c.626+1G>A p.X209_splice | Splice Site (SNP) | VAF 49/205 reads (24%) | catalogued as rs1555358507, CS042541, CS093877, CS983481, COSV54303542; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1064797027; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HTRA1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 74/288 reads (26%) | catalogued as rs113993970, CM092290; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KCNH2 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs794728383, CM1211301, COSV51221089; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KDM5C | c.2332C>T p.R778* | Nonsense Mutation (SNP) | VAF 26/401 reads (6%) | catalogued as rs1556840029, COSV64764544; ClinVar: pathogenic; called by muse, mutect2
- KMT2C | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 36/314 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1403418496, COSV51343575; called by muse, varscan2
- MEF2C | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 122/549 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052728; ClinVar: pathogenic; called by muse, varscan2
- MSH2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 83/402 reads (21%) | catalogued as rs63749947, CD076834, CM076317, COSV51875855, COSV51883753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 80/430 reads (19%) | catalogued as rs587783792, CM971002; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NARS2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367584549, COSV55250404; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 35/266 reads (13%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NEB | c.1470+1G>A p.X490_splice | Splice Site (SNP) | VAF 72/267 reads (27%) | catalogued as rs1220787593, COSV50805874, COSV99419499; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 77/419 reads (18%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs587783921, COSV56940971; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PEX3 | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 92/393 reads (23%) | catalogued as rs201179294; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 186/644 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 64/432 reads (15%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 78/426 reads (18%) | catalogued as rs1057516768; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKP2 | c.2484C>T p.G828= | Silent (SNP) | VAF 57/236 reads (24%) | catalogued as rs727504509, CS065607, COSV50728278; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 32/167 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PORCN | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 58/327 reads (18%) | catalogued as rs137852218, CM073270, COSV100400509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 50/347 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- PRKCI | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 72/349 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV55519623; called by muse, mutect2, varscan2
- PRLR | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 28/260 reads (11%) | catalogued as rs376188691, COSV51492949; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 112/480 reads (23%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- REN | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 54/312 reads (17%) | catalogued as rs121917740, CM941216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RP1 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 80/371 reads (22%) | catalogued as rs201493928, CM1312698; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPE65 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 53/368 reads (14%) | catalogued as rs61752895, CM971315, COSV52018230; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RS1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs281865355, CM001333, CM981764; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 88/296 reads (30%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, varscan2
- RYR1 | c.14209C>T p.R4737W | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs193922867, CM023979; ClinVar: pathogenic; called by muse, varscan2
- RYR1 | c.14489C>A p.S4830Y | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555803852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.5644C>T p.R1882* | Nonsense Mutation (SNP) | VAF 72/298 reads (24%) | catalogued as rs796053166, CM162377, COSV99334228; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCNN1B | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72654338, CM056056; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SDHC | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205147, CM092188; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- SERPINC1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 109/472 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs121909563, CM900039; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SLC2A9 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372201423, CM153726; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLCO2A1 | c.940+1G>A p.X314_splice | Splice Site (SNP) | VAF 54/178 reads (30%) | catalogued as rs765249238, CS120195; ClinVar: pathogenic; called by muse, varscan2
- SMAD3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906853, CM116903, COSV59283256, COSV59285961; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SPARC | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1057517662, CM155189, COSV50559547; ClinVar: pathogenic; called by muse, varscan2
- STING1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777610, CM147523; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNGAP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 104/419 reads (25%) | catalogued as rs1554121443; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TAZ | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307797, CM024152, CM046066, COSV100173351; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TBL1XR1 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 111/536 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs878854402, CM164586, COSV70500760; ClinVar: pathogenic; called by muse, varscan2
- TBL1XR1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 129/427 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs1057517933, CM162314, COSV70501537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200491579, CM091315; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TNNI3 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs727503499, CM113585, COSV52572608; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 44/180 reads (24%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 66/284 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 61/240 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53244109; called by muse, mutect2, varscan2
- TSC1 | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 50/265 reads (19%) | catalogued as rs886039662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.4919A>G p.H1640R | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs794727602; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.101608+1G>A p.X33870_splice (on ENST00000591111; = p.X26446_splice on NM_003319.4) | Splice Site (SNP) | VAF 35/249 reads (14%) | catalogued as rs760915007; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.4411C>T p.R1471* | Nonsense Mutation (SNP) | VAF 133/505 reads (26%) | catalogued as rs386834086, CM090643, COSV62151221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WNT10A | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374910216; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199692344; called by muse, varscan2
- AACS | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022690870; called by muse, mutect2, varscan2
- AADAC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 87/425 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs762922385, COSV99233496; called by muse, mutect2, varscan2
- AADACL3 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.315); catalogued as rs772061836; called by muse, mutect2, varscan2
- AAK1 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.964); catalogued as rs760673177; called by muse, mutect2, varscan2
- AAK1 | c.1599G>C p.Q533H | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1263928487; called by muse, mutect2, varscan2
- AARS2 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs751523537, COSV99771632; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AATK | c.3623G>A p.R1208H (on ENST00000326724 / NM_001080395.3; = p.R1105H on NM_004920.2) | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370976937; called by muse, mutect2, varscan2
- AATK | c.1459G>A p.A487T (on ENST00000326724 / NM_001080395.3; = p.A384T on NM_004920.2) | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.215); catalogued as rs765506632; called by muse, varscan2
- ABCA1 | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs375234343; called by muse, varscan2
- ABCA10 | c.4105G>A p.G1369R | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779392624; called by muse, mutect2, varscan2
- ABCA12 | c.6463G>A p.G2155S (on ENST00000272895 / NM_173076.3; = p.G1837S on NM_015657.3) | Missense Mutation (SNP) | VAF 111/481 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750214847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.5404G>T p.A1802S (on ENST00000272895 / NM_173076.3; = p.A1484S on NM_015657.3) | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV55977326; called by muse, varscan2
- ABCA12 | c.3674G>A p.R1225Q (on ENST00000272895 / NM_173076.3; = p.R907Q on NM_015657.3) | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs761166029, COSV55956266; called by muse, mutect2, varscan2
- ABCA12 | c.2683G>A p.D895N (on ENST00000272895 / NM_173076.3; = p.D577N on NM_015657.3) | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs1559141294, COSV55965075, COSV99788147; ClinVar: uncertain significance; called by muse, mutect2
- ABCA13 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as rs1256715219; called by muse, mutect2, varscan2
- ABCA13 | c.12586G>A p.A4196T | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV68949879; called by muse, mutect2
- ABCA2 | c.4970C>T p.S1657L (on ENST00000614293; = p.S1627L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs749362777; called by muse, mutect2, varscan2
- ABCA2 | c.2641G>A p.A881T (on ENST00000614293; = p.A851T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1396280548, COSV99687164; called by muse, mutect2, varscan2
- ABCA4 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs548888187, COSV64672582; called by muse, varscan2
- ABCA4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 54/368 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs769541140; called by muse, varscan2
- ABCA5 | c.4214G>T p.S1405I | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.581); catalogued as COSV67015681; called by muse, varscan2
- ABCA7 | c.3080G>A p.R1027H | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs146278525; called by muse, varscan2
- ABCA7 | c.3352C>T p.R1118* | Nonsense Mutation (SNP) | VAF 45/258 reads (17%) | catalogued as rs766318027, COSV54032378; called by muse, mutect2, varscan2
- ABCA7 | c.5926C>T p.R1976C | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs906507214, COSV99566804; called by muse, mutect2, varscan2
- ABCA8 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199640898, COSV52197689, COSV52199617; called by muse, mutect2, varscan2
- ABCA9 | c.3398G>T p.R1133I | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100383310, COSV100383702; called by muse, mutect2, varscan2
- ABCA9 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100383006; called by muse, mutect2
- ABCA9 | c.754A>C p.I252L | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60624705; called by muse, varscan2
- ABCA9 | c.576C>T p.I192= | Splice Region (SNP) | VAF 39/212 reads (18%) | catalogued as rs777966131, COSV100383290, COSV60627123; called by muse, varscan2
- ABCB11 | c.3827G>A p.R1276H | Missense Mutation (SNP) | VAF 109/522 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777458071, COSV55592328; called by muse, mutect2, varscan2
- ABCB4 | c.2211G>A p.A737= | Splice Region (SNP) | VAF 32/224 reads (14%) | catalogued as rs763404399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 110/511 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB6 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs768341073; called by muse, mutect2, varscan2
- ABCB8 | c.1099C>T p.R367W (on ENST00000297504 / NM_001282291.2; = p.R350W on NM_007188.5) | Missense Mutation (SNP) | VAF 76/418 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as rs200124806; called by muse, mutect2, varscan2
- ABCB9 | c.1960G>A p.A654T (on ENST00000280560 / NM_019625.4; = p.A611T on NM_019624.3) | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273628402; called by muse, mutect2, varscan2
- ABCC1 | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs1037769867, COSV60696093; called by muse, mutect2, varscan2
- ABCC10 | c.4361C>T p.A1454V (on ENST00000372530 / NM_001198934.2; = p.A1426V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs777467243, COSV99767598; called by muse, varscan2
- ABCC11 | c.1256G>A p.S419N | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV100751330; called by muse, mutect2, varscan2
- ABCC11 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs199620156, COSV62322013; called by muse, mutect2, varscan2
- ABCC5 | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55589541; called by muse, mutect2, varscan2
- ABCC5 | c.1354T>C p.F452L | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1451196246; called by muse, mutect2, varscan2
- ABCC5 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778051283, COSV55597216; called by muse, mutect2, varscan2
- ABCC8 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1057467571, COSV100217760; called by muse, mutect2, varscan2
- ABCD4 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV53992342; called by muse, mutect2, varscan2
- ABCE1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 107/344 reads (31%) | catalogued as COSV99668520; called by muse, mutect2, varscan2
- ABCF2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 109/369 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs752398993; called by muse, mutect2, varscan2
- ABCF3 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53054148; called by muse, mutect2, varscan2
- ABCG2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 139/406 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs139903768; called by muse, mutect2, varscan2
- ABCG5 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756734792, COSV99575586; called by muse, mutect2, varscan2
- ABCG8 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374361804, COSV99699448; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs775409508; called by muse, mutect2, varscan2
- ABHD16B | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 118/429 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs776219427; called by muse, mutect2, varscan2
- ABHD17A | c.766G>A p.E256K (on ENST00000292577 / NM_001130111.2; = p.E307K on NM_031213.4) | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1381584788, COSV99171191; called by muse, mutect2
- ABI1 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61016732; called by muse, mutect2, varscan2
- ABI3 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs769714351, COSV56799151; called by muse, mutect2, varscan2
- ABL2 | c.1952G>A p.G651D (on ENST00000502732 / NM_007314.4; = p.G636D on NM_005158.5) | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV61012366, COSV61021327; called by muse, mutect2, varscan2
- ABL2 | c.1165A>G p.M389V (on ENST00000502732 / NM_007314.4; = p.M374V on NM_005158.5) | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs762813604; called by muse, varscan2
- ABL2 | c.1052G>A p.C351Y (on ENST00000502732 / NM_007314.4; = p.C336Y on NM_005158.5) | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761705401; called by muse, varscan2
- ABLIM2 | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56403856; called by muse, varscan2
- ABR | c.856G>A p.D286N (on ENST00000302538 / NM_021962.5; = p.D249N on NM_001092.5) | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.349); catalogued as rs766375955; called by muse, varscan2
- ABTB1 | c.1277C>T p.A426V (on ENST00000232744 / NM_172027.3; = p.A284V on NM_032548.3) | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs148820470; called by muse, mutect2, varscan2
- ABTB2 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs562480717; called by muse, mutect2, varscan2
- ABTB2 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs151258781; called by muse, mutect2, varscan2
- ABTB2 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750330268, COSV54384663; called by muse, mutect2, varscan2
- AC004593.2 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 61/477 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56102223; called by muse, mutect2, varscan2
- AC005324.2 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.199); catalogued as rs761828593; called by muse, mutect2, varscan2
- AC005551.1 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1295705598; called by muse, mutect2
- AC068580.4 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs775579878; called by muse, mutect2, varscan2
- AC073111.3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1293197933; called by muse, mutect2
- AC090517.4 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50996313, COSV99974591; called by muse, mutect2, varscan2
- AC092718.8 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs767679737, COSV59601504; called by muse, mutect2, varscan2
- AC092835.1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 66/428 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1368703628; called by muse, mutect2, varscan2
- AC099489.1 | c.9079G>A p.D3027N | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs913794792; called by muse, varscan2
- AC099489.1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as rs189850688; called by muse, varscan2
- AC105001.2 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 53/470 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs779737557; called by muse, varscan2
- AC138647.1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.815); catalogued as rs1432912494; called by muse, varscan2
- AC138647.1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1191055371; called by muse, varscan2
- AC244197.3 | c.472T>C p.S158P | Missense Mutation (SNP) | VAF 70/678 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1557338128; called by muse, mutect2, varscan2
- AC253536.7 | c.327G>A p.R109= | Splice Region (SNP) | VAF 60/283 reads (21%) | catalogued as rs779750125, COSV53159502; called by muse, mutect2, varscan2
- ACACA | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs756880093; called by muse, mutect2, varscan2
- ACACB | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs754505331; called by muse, mutect2, varscan2
- ACACB | c.6968G>A p.R2323H | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs147616769; called by muse, mutect2, varscan2
- ACAD9 | c.1679A>G p.N560S | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as rs762458764; called by muse, mutect2, varscan2
- ACADL | c.202T>A p.F68I | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.791); catalogued as COSV52053021; called by mutect2, varscan2
- ACAP2 | c.904T>A p.F302I | Missense Mutation (SNP) | VAF 87/523 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs1045333391, COSV100462667; called by muse, mutect2, varscan2
- ACAP3 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174245711; called by muse, varscan2
- ACAP3 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs367705468; called by muse, mutect2, varscan2
- ACBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 88/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278923333, COSV64729525; called by muse, mutect2, varscan2
- ACE2 | c.2015T>C p.V672A | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.045); catalogued as rs1449878623; called by muse, mutect2, varscan2
- ACKR1 | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV63674583; called by muse, mutect2, varscan2
- ACMSD | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.189); catalogued as rs779680562, COSV51607683; called by muse, mutect2, varscan2
- ACMSD | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 45/358 reads (13%) | catalogued as rs370807501; called by muse, varscan2
- ACOD1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs966231606; called by muse, mutect2
- ACOX2 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs759724683; called by muse, mutect2, varscan2
- ACP2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs776348174; called by muse, mutect2, varscan2
- ACP3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777524768, COSV60488700; called by muse, mutect2, varscan2
- ACR | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs1334636659; called by muse, mutect2, varscan2
- ACR | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs370250594; called by muse, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by muse, mutect2, varscan2
- ACSBG1 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.115); catalogued as rs745591902, COSV51911771; called by mutect2, varscan2
- ACSBG2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs754295937; called by muse, varscan2
- ACSBG2 | c.1724A>C p.N575T | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99397253; called by muse, mutect2, varscan2
- ACSL6 | c.1148C>T p.T383I (on ENST00000379240; = p.T408I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs753644715; called by muse, mutect2, varscan2
- ACSL6 | c.841G>T p.G281W (on ENST00000379240; = p.G306W on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183861994; called by muse, mutect2, varscan2
- ACSM1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147062129; called by muse, mutect2, varscan2
- ACSM4 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 105/463 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781213298, COSV101257289, COSV68068688; called by muse, mutect2, varscan2
- ACSM4 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 88/360 reads (24%) | catalogued as COSV101257389; called by mutect2, varscan2
- ACSM5 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs750836384, COSV59374964; called by muse, varscan2
- ACSS3 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 62/570 reads (11%) | catalogued as rs140163993; called by muse, mutect2, varscan2
- ACTA1 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM012325, CM034511, CM045914, CX095261, COSV64203015; called by muse, varscan2
- ACTA1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64202946; called by muse, mutect2, varscan2
- ACTA1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.161); catalogued as COSV64203495; called by muse, mutect2, varscan2
- ACTA2 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554841990; ClinVar: uncertain significance; called by muse, mutect2
- ACTG1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); catalogued as rs11549225, COSV59509724; called by muse, mutect2, varscan2
- ACTL7A | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1048387362; called by muse, mutect2, varscan2
- ACTN2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV63972665; called by muse, mutect2, varscan2
- ACTN2 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370569935; ClinVar: uncertain significance; called by muse, varscan2
- ACTR3B | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99754647; called by muse, mutect2, varscan2
- ADAD1 | c.244dup p.I82Nfs*3 | Frame Shift Ins (INS) | VAF 43/318 reads (14%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAD2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 80/475 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV51894104, COSV51894179; called by muse, mutect2, varscan2
- ADAM15 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs777569225, COSV55129631; called by muse, mutect2, varscan2
- ADAM19 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs200776477, COSV99978791; called by muse, mutect2, varscan2
- ADAM22 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1344980431; called by muse, mutect2, varscan2
- ADAM22 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs751815014; called by muse, mutect2, varscan2
- ADAM28 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs750962690; called by muse, mutect2, varscan2
- ADAM9 | c.2195G>T p.R732I | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV65960542; called by muse, varscan2
- ADAMDEC1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 58/270 reads (21%) | catalogued as COSV56474525; called by mutect2, varscan2
- ADAMTS12 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1287419281, COSV61257410; called by muse, mutect2, varscan2
- ADAMTS14 | c.622C>A p.R208S | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV64600156; called by muse, mutect2, varscan2
- ADAMTS15 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs267602782, COSV54504881; called by muse, mutect2, varscan2
- ADAMTS15 | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 112/457 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1169596109; called by muse, mutect2, varscan2
- ADAMTS16 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 112/516 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1431159881, COSV57010074; called by muse, mutect2, varscan2
- ADAMTS16 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377507889; called by muse, mutect2, varscan2
- ADAMTS16 | c.2755C>A p.L919M | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV99940838; called by muse, varscan2
- ADAMTS16 | c.2776G>C p.A926P | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755948868; called by muse, varscan2
- ADAMTS17 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs377387249; called by muse, varscan2
- ADAMTS17 | c.1957C>A p.L653M | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.091); catalogued as COSV51493755; called by muse, mutect2
- ADAMTS18 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs189744529, COSV51401748; called by muse, mutect2, varscan2
- ADAMTS18 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51419928; called by muse, mutect2, varscan2
- ADAMTS18 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs773875816; called by muse, mutect2, varscan2
- ADAMTS19 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 97/416 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs766949011, COSV50755296; called by muse, mutect2, varscan2
- ADAMTS19 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50745026; called by muse, mutect2, varscan2
- ADAMTS2 | c.3311G>A p.G1104D | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52393757; called by muse, mutect2, varscan2
- ADAMTS2 | c.3088+1G>A p.X1030_splice | Splice Site (SNP) | VAF 34/148 reads (23%) | catalogued as COSV52367932; called by muse, varscan2
- ADAMTS2 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775351961; called by muse, mutect2, varscan2
- ADAMTS2 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs771811363; called by muse, mutect2, varscan2
- ADAMTS2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV51123660; called by muse, mutect2
- ADAMTS20 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 92/448 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs372581152; called by muse, varscan2
- ADAMTS4 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs774531559; called by muse, mutect2, varscan2
- ADAMTS4 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1343826431, COSV63487304, COSV63488443; called by muse, mutect2
- ADAMTS7 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs751279737; called by muse, mutect2, varscan2
- ADAMTS7 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.872); catalogued as rs760884861; called by muse, mutect2, varscan2
- ADAMTS9 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 142/484 reads (29%) | catalogued as COSV55781008; called by muse, mutect2, varscan2
- ADAMTSL3 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV54442157; called by muse, mutect2
- ADAMTSL4 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433260668, COSV54999079, COSV55004765; called by muse, varscan2
- ADAT3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs778969688; called by muse, mutect2, varscan2
- ADCK1 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs565870217; called by muse, mutect2, varscan2
- ADCK5 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781975682, COSV100450881; called by muse, mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, varscan2
- ADCY2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs755729905; called by muse, mutect2, varscan2
- ADCY5 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs1324655717, COSV59193487, COSV59200545; called by muse, mutect2
- ADCY5 | c.1814A>G p.H605R | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240324735; called by muse, mutect2, varscan2
- ADCY6 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs767688936; called by muse, mutect2, varscan2
- ADCY7 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.155); catalogued as rs746900335, COSV54265488; called by muse, mutect2, varscan2
- ADCY7 | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371865539; called by muse, mutect2, varscan2
- ADCY9 | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1278739094; called by muse, varscan2
- ADCY9 | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs750492924; called by muse, mutect2, varscan2
- ADCY9 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV53571802; called by muse, mutect2, varscan2
- ADCY9 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53578500; called by muse, varscan2
- ADD1 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99297023; called by mutect2, varscan2
- ADD2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs373747708, COSV52464232; called by muse, mutect2, varscan2
- ADGB | c.4585C>T p.R1529* | Nonsense Mutation (SNP) | VAF 104/448 reads (23%) | catalogued as rs1240602803, COSV58849886; called by muse, varscan2
- ADGRA2 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1335523011; called by muse, mutect2
- ADGRA2 | c.2677G>T p.G893W | Missense Mutation (SNP) | VAF 69/339 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55103040; called by muse, mutect2, varscan2
- ADGRB1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60091183; called by muse, mutect2, varscan2
- ADGRB1 | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs763568395; called by muse, mutect2, varscan2
- ADGRB2 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.094); catalogued as rs1044701143, COSV57075275; called by muse, mutect2, varscan2
- ADGRB3 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 73/367 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV65414194; called by muse, mutect2, varscan2
- ADGRB3 | c.3538G>A p.G1180R | Missense Mutation (SNP) | VAF 101/428 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53252248; called by muse, mutect2, varscan2
- ADGRB3 | c.3763G>T p.G1255C | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.436); catalogued as COSV99484915; called by muse, mutect2, varscan2
- ADGRD1 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1294123576; called by muse, mutect2, varscan2
- ADGRD1 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as rs374985420; called by muse, mutect2, varscan2
- ADGRD1 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.443); catalogued as rs750045616; called by muse, mutect2, varscan2
- ADGRD2 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 40/223 reads (18%) | catalogued as rs1410559535, COSV100601115; called by muse, mutect2, varscan2
- ADGRE1 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.69); catalogued as rs749522542; called by muse, mutect2, varscan2
- ADGRE5 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs563311457; called by muse, mutect2, varscan2
- ADGRF5 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs139730967; called by muse, mutect2, varscan2
- ADGRG2 | c.2057C>T p.A686V (on ENST00000379869 / NM_001079858.3; = p.A683V on NM_005756.4) | Missense Mutation (SNP) | VAF 106/469 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1349171978; called by muse, mutect2, varscan2
- ADGRG3 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59653005; called by muse, mutect2, varscan2
- ADGRG4 | c.3819G>T p.E1273D | Missense Mutation (SNP) | VAF 87/449 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54955901; called by muse, mutect2, varscan2
- ADGRG4 | c.8482G>T p.G2828C | Missense Mutation (SNP) | VAF 66/710 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99796088; called by muse, mutect2
- ADGRG6 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 84/333 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as rs756610632, COSV51589664; called by muse, mutect2, varscan2
- ADGRG7 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 72/425 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs191755803; called by muse, mutect2, varscan2
- ADGRL2 | c.1138T>C p.W380R | Missense Mutation (SNP) | VAF 96/384 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99588286; called by muse, mutect2, varscan2
- ADGRL2 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 118/511 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1027193209; called by muse, mutect2, varscan2
- ADGRL3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101547324; called by muse, mutect2, varscan2
- ADGRL3 | c.2194C>T p.R732C (on ENST00000506720 / NM_001322402.2; = p.R664C on NM_015236.6) | Missense Mutation (SNP) | VAF 148/422 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs755969418, COSV72230572; called by muse, varscan2
- ADGRV1 | c.207G>A p.S69= | Splice Region (SNP) | VAF 44/236 reads (19%) | catalogued as rs769561134, COSV67992162; called by muse, mutect2, varscan2
- ADGRV1 | c.3433G>T p.G1145* | Nonsense Mutation (SNP) | VAF 44/337 reads (13%) | catalogued as rs866961759, COSV67991319; called by mutect2, varscan2
- ADGRV1 | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs767740072, COSV67979441; called by muse, mutect2, varscan2
- ADGRV1 | c.9661G>A p.V3221M | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs368092861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.11038C>T p.R3680C | Missense Mutation (SNP) | VAF 100/459 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367738566; called by muse, varscan2
- ADH7 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs764699940; called by muse, mutect2, varscan2
- ADHFE1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs202089911, COSV52555232; called by muse, mutect2, varscan2
- ADORA2A | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100418116; called by muse, mutect2, varscan2
- ADORA2B | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs1021224191, COSV58483714; called by muse, mutect2, varscan2
- ADPRHL1 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.355); catalogued as rs1445251025; called by muse, mutect2, varscan2
- ADPRHL1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs760737716; called by muse, mutect2, varscan2
- ADPRHL1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766539065, COSV100733318; called by muse, mutect2, varscan2
- ADRA1A | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.03); catalogued as COSV52360886, COSV52363717; called by muse, mutect2, varscan2
- ADRA1A | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747122943; called by muse, mutect2, varscan2
- ADRA2B | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV69787508; called by muse, mutect2, varscan2
- ADRA2C | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342874997, COSV100342709; called by muse, varscan2
- ADRB1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as rs1564887005; called by muse, varscan2
- ADRB2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs776447135; called by muse, mutect2, varscan2
- ADSS1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs1183826258; called by muse, mutect2, varscan2
- AF196969.1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs782358140, COSV52141525, COSV52142166; called by muse, mutect2, varscan2
- AFAP1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 26/258 reads (10%) | catalogued as rs749129062, COSV61794643; called by muse, mutect2, varscan2
- AFAP1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61795494; called by muse, mutect2, varscan2
- AFAP1L1 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs969182346; called by muse, mutect2, varscan2
- AFAP1L2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1030245150, COSV58414293; called by muse, mutect2, varscan2
- AFDN | c.5386C>T p.R1796C (on ENST00000447894 / NM_001366320.1; = p.R1715C on NM_001207008.1) | Missense Mutation (SNP) | VAF 55/498 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1200231540; called by muse, mutect2, varscan2
- AFG1L | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs748511578; called by muse, mutect2, varscan2
- AGAP1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs758678583; called by muse, mutect2, varscan2
- AGAP1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as rs1024327166; called by muse, mutect2, varscan2
- AGAP2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57727123; called by mutect2, varscan2
- AGAP5 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs751244541, COSV65070128; called by muse, varscan2
- AGBL1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775341691, COSV69803865; called by muse, mutect2, varscan2
- AGBL4 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs755308164; called by muse, mutect2, varscan2
- AGBL4 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs771499735, COSV61893448; called by muse, varscan2
- AGBL4 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464410305; called by muse, mutect2, varscan2
- AGER | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 105/478 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs772300820; called by muse, mutect2, varscan2
- AGGF1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs202148839; called by muse, mutect2, varscan2
- AGL | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as rs746265668, COSV54052510; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768762536, COSV65435721; called by muse, mutect2, varscan2
- AGO2 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1431074938; called by muse, mutect2, varscan2
- AGO2 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs1045459491; called by muse, mutect2, varscan2
- AGO4 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100942788, COSV64617285; called by muse, mutect2, varscan2
- AGO4 | c.1566G>A p.A522= | Splice Region (SNP) | VAF 30/153 reads (20%) | catalogued as rs569995605, COSV64616808; called by muse, mutect2, varscan2
- AGPAT3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs540217428; called by muse, mutect2, varscan2
- AGPAT4 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1372957019; called by muse, mutect2
- AGPS | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 90/423 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931203; called by muse, mutect2, varscan2
- AGRN | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs375076629; called by muse, mutect2, varscan2
- AGRN | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs201651738; called by muse, mutect2, varscan2
- AGTPBP1 | c.2423A>C p.K808T (on ENST00000357081 / NM_001330701.2; = p.K768T on NM_015239.2) | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61272598; called by muse, mutect2, varscan2
- AGXT2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs760978202, COSV51485242; called by muse, mutect2, varscan2
- AGXT2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs756036796, COSV51487388; called by mutect2, varscan2
- AHCTF1 | c.1349C>T p.S450L (on ENST00000366508; = p.S424L on NM_015446.5) | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs528013816, COSV58246078; called by muse, mutect2, varscan2
- AHCTF1 | c.911C>T p.A304V (on ENST00000366508; = p.A278V on NM_015446.5) | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750591278; called by muse, mutect2, varscan2
- AHDC1 | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs914335874; called by muse, mutect2, varscan2
- AHDC1 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs923632705, COSV55940700; called by muse, mutect2, varscan2
- AHDC1 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1025425807; called by muse, mutect2, varscan2
- AHDC1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs768575414; called by muse, mutect2, varscan2
- AHNAK | c.6494C>T p.A2165V | Missense Mutation (SNP) | VAF 49/487 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs756775428, COSV99945479; called by muse, mutect2, varscan2
- AHNAK | c.3634G>A p.D1212N | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as rs1020579212; called by muse, mutect2, varscan2
- AHNAK2 | c.9947C>T p.P3316L | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs185803383; called by muse, mutect2, varscan2
- AHNAK2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV60913357; called by muse, mutect2, varscan2
- AHRR | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs758247951; called by muse, mutect2, varscan2
- AIFM2 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.293); catalogued as rs368126515, COSV100325778; called by muse, mutect2, varscan2
- AIFM3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs747011410, COSV53146636; called by muse, varscan2
- AIG1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs957802811; called by muse, varscan2
- AIRE | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CS087286; called by mutect2, varscan2
- AJAP1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs779291510; called by muse, varscan2
- AJAP1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV65452326; called by muse, mutect2, varscan2
- AKAP13 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs114690403; called by muse, mutect2, varscan2
- AKAP13 | c.4723G>A p.D1575N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs148772528; called by mutect2, varscan2
- AKAP17A | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 108/468 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.729); catalogued as COSV58308368; called by muse, varscan2
- AKAP17A | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 125/604 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1204041488; called by muse, mutect2, varscan2
- AKAP17A | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 105/464 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.558); catalogued as rs141304647, COSV99047626; called by muse, varscan2
- AKAP17A | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.245); catalogued as rs778466247; called by muse, mutect2, varscan2
- AKAP3 | c.794G>T p.R265I | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV57422001; called by muse, mutect2, varscan2
- AKAP5 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs375866913, COSV100277906; called by muse, mutect2, varscan2
- AKAP6 | c.5861C>T p.S1954F | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs201421428, COSV99797328; called by muse, mutect2, varscan2
- AKAP8 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs772661694; called by muse, mutect2, varscan2
- AKAP8L | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.814); catalogued as rs1242829689; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AKAP9 | c.6650C>T p.A2217V (on ENST00000359028; = p.A2193V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs1196844754; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 91/378 reads (24%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKAP9 | c.11411T>G p.F3804C (on ENST00000359028; = p.F3780C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62345036; called by muse, mutect2, varscan2
- AKNA | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs750708829, COSV56339609; called by muse, varscan2
- AKNA | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs777135855; called by muse, mutect2, varscan2
- AKNAD1 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs368439907; called by muse, mutect2, varscan2
- AL035460.1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 86/366 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.072); catalogued as rs375610027; called by muse, mutect2, varscan2
- AL121899.2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs143797112; called by muse, mutect2, varscan2
- AL121899.2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs556533732, COSV101198521; called by muse, varscan2
- AL354761.1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs1045043935; called by muse, mutect2, varscan2
- AL358113.1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 52/248 reads (21%) | catalogued as rs768870216; called by muse, varscan2
- AL441992.2 | c.*1246C>T | Splice Region (SNP) | VAF 42/164 reads (26%) | catalogued as rs774159371; called by muse, varscan2
- ALDH1A2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs769522277, COSV51090735; called by muse, mutect2
- ALDH1A3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs370671214; called by mutect2, varscan2
- ALDH1L1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs748153094; called by muse, mutect2, varscan2
- ALDH1L1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.319); catalogued as rs747762366; called by muse, mutect2, varscan2
- ALDH3A1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200726755, COSV104387613; called by muse, mutect2, varscan2
- ALDH3B1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1157585732, COSV99141780; called by muse, mutect2, varscan2
- ALDH3B1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs865916355, COSV50287861, COSV50291066; called by muse, varscan2
- ALDH3B2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs761186674; called by muse, mutect2, varscan2
- ALG13 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764522101; called by muse, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 272/622 reads (44%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 50/254 reads (20%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALG3 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 93/369 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.533); catalogued as rs537211234; called by muse, mutect2, varscan2
- ALK | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV66591587; called by muse, mutect2, varscan2
- ALKBH6 | c.365C>T p.P122L (on ENST00000252984 / NM_001297701.2; = p.P150L on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs3204366; called by muse, varscan2
- ALOX12 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52350870; called by muse, mutect2, varscan2
- ALPG | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs375292491; called by muse, mutect2
- ALPG | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1559247504; called by muse, varscan2
- ALPG | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); catalogued as rs201503000; called by muse, varscan2
- ALPI | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1158171138, COSV55013640; called by muse, mutect2, varscan2
- ALPK1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188866014; called by muse, mutect2, varscan2
- ALPK1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs775130609; called by muse, mutect2, varscan2
- ALPK2 | c.4219G>A p.D1407N | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as COSV64498215; called by muse, mutect2
- ALPL | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100876139; called by muse, mutect2
- ALPP | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs781682267, COSV67398312; called by muse, mutect2, varscan2
- ALS2 | c.2321A>G p.H774R | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs747038450; called by muse, mutect2, varscan2
- ALX4 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1014714152, COSV100241121; called by muse, mutect2, varscan2
- AMDHD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 95/388 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758223660, COSV57137813; called by muse, mutect2, varscan2
- AMER1 | c.2700G>T p.E900D | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); catalogued as COSV57667461; called by muse, varscan2
- AMER1 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs904761868, COSV57655652; called by muse, mutect2
- AMER2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs757705946; called by muse, mutect2, varscan2
- AMFR | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs773814282; called by muse, mutect2, varscan2
- AMH | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs569914235, CM940047, COSV55555036; called by muse, varscan2
- AMHR2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs374943863; called by muse, mutect2, varscan2
- AMIGO3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs780229420, COSV100246608; called by muse, mutect2, varscan2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, mutect2, varscan2
- AMOTL1 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs748264068, COSV58565332; called by muse, mutect2, varscan2
- AMPD2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 44/267 reads (16%) | catalogued as rs1427869766; called by muse, mutect2, varscan2
- AMY2A | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 52/848 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV70214793; called by muse, mutect2
- ANAPC10 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1025493515, COSV58739849; called by muse, mutect2, varscan2
- ANAPC2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs1448409852; called by muse, mutect2, varscan2
- ANAPC4 | c.796A>C p.N266H | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs765587767; called by muse, mutect2, varscan2
- ANAPC5 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778284423, COSV55843415; called by muse, varscan2
- ANGPTL1 | c.605G>T p.R202M | Missense Mutation (SNP) | VAF 128/487 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV99327932; called by muse, mutect2, varscan2
- ANGPTL1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 93/449 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs979372722; called by muse, mutect2, varscan2
- ANHX | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs913518117, COSV101376500; called by muse, mutect2, varscan2
- ANK1 | c.5485C>T p.R1829C | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as rs751690725; called by muse, mutect2, varscan2
- ANK1 | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1428777679, COSV55888428; called by muse, mutect2, varscan2
- ANK1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369233964, COSV55889961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1327848108, COSV52183131; called by muse, mutect2, varscan2
- ANK2 | c.2968C>T p.R990* | Nonsense Mutation (SNP) | VAF 110/323 reads (34%) | catalogued as rs1554508985, COSV52154619, COSV52189578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.4736C>T p.S1579L | Missense Mutation (SNP) | VAF 103/461 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs896865622, COSV55052590; called by muse, mutect2, varscan2
- ANK3 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs140444175; called by muse, varscan2
- ANKAR | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 72/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs750922987, COSV55610460; called by muse, mutect2, varscan2
- ANKEF1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 99/388 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101000984; called by muse, mutect2, varscan2
- ANKEF1 | c.2271G>A p.M757I | Missense Mutation (SNP) | VAF 105/433 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV65693496; called by muse, mutect2, varscan2
- ANKFN1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV100593997; called by muse, mutect2
- ANKFY1 | c.3182G>A p.R1061H (on ENST00000341657 / NM_001330063.2; = p.R1062H on NM_016376.5) | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs367586240; called by muse, mutect2, varscan2
- ANKIB1 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as rs760743621, COSV56061265; called by muse, mutect2, varscan2
- ANKLE1 | c.1445C>T p.A482V (on ENST00000394458; = p.A428V on NM_152363.6) | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs146387346; called by muse, mutect2, varscan2
- ANKMY2 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200413443; called by muse, mutect2, varscan2
- ANKRD1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs1293523344, COSV65467209; called by muse, mutect2, varscan2
- ANKRD11 | c.7834G>A p.E2612K | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56360790; called by muse, mutect2, varscan2
- ANKRD11 | c.7582G>A p.V2528I | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1417276333; called by muse, mutect2, varscan2
- ANKRD13B | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs751825001, COSV61472563; called by muse, mutect2, varscan2
- ANKRD13B | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); catalogued as rs1403646075, COSV100801076; called by muse, mutect2, varscan2
- ANKRD13C | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs144733444; called by mutect2, varscan2
- ANKRD18A | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 99/411 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.208); catalogued as COSV68803645; called by muse, mutect2, varscan2
- ANKRD2 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1361248381; called by muse, mutect2, varscan2
- ANKRD20A1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1430617790; called by muse, mutect2, varscan2
- ANKRD20A1 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs914745367; called by muse, varscan2
- ANKRD24 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs368240733; called by muse, mutect2, varscan2
- ANKRD27 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762117215, COSV60136125; called by muse, mutect2, varscan2
- ANKRD27 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs545576973; called by muse, mutect2, varscan2
- ANKRD28 | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs768759447; called by muse, mutect2, varscan2
- ANKRD34C | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1275073756; called by muse, mutect2, varscan2
- ANKRD36 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs749026163, COSV70403030; called by muse, mutect2, varscan2
- ANKRD36 | c.4750C>T p.R1584C | Missense Mutation (SNP) | VAF 111/607 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs778347864, COSV100825878; called by muse, mutect2, varscan2
- ANKRD36C | c.2329G>A p.G777R | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1344500136; called by muse, mutect2, varscan2
- ANKRD39 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144293475; called by muse, mutect2, varscan2
- ANKRD44 | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 30/445 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as rs1234588488; called by muse, mutect2
- ANKRD44 | c.1408T>C p.W470R | Missense Mutation (SNP) | VAF 122/546 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV56564742; called by muse, mutect2, varscan2
- ANKRD50 | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 49/521 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs751696858; called by muse, mutect2
- ANKRD60 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs565683004; called by muse, mutect2, varscan2
- ANKRD9 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414533472; called by muse, mutect2, varscan2
- ANKS1A | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs759146653, CM1412368; called by muse, mutect2, varscan2
- ANKS1B | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178191342; called by muse, mutect2, varscan2
- ANKS3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1200272001, COSV58507386; called by muse, mutect2
- ANKS6 | c.2264C>T p.S755L | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs370230003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKUB1 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 138/476 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV101267487; called by muse, mutect2, varscan2
- ANKZF1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1448337254, COSV55479327; called by muse, varscan2
- ANO2 | c.1984G>A p.E662K (on ENST00000356134 / NM_001278597.3; = p.E666K on NM_001278596.3) | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV59008703, COSV59045108; called by muse, mutect2, varscan2
- ANO2 | c.1798G>A p.A600T (on ENST00000356134 / NM_001278597.3; = p.A604T on NM_001278596.3) | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59020301; called by muse, mutect2, varscan2
- ANO2 | c.437C>T p.A146V (on ENST00000356134 / NM_001278597.3; = p.A150V on NM_001278596.3) | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV59034146; called by muse, mutect2, varscan2
- ANO4 | c.1446G>A p.M482I (on ENST00000392977 / NM_001286615.2; = p.M447I on NM_178826.4) | Missense Mutation (SNP) | VAF 124/538 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV54612995; called by muse, mutect2, varscan2
- ANO4 | c.2369C>T p.A790V (on ENST00000392977 / NM_001286615.2; = p.A755V on NM_178826.4) | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763712389, COSV100151981; called by muse, mutect2, varscan2
- ANO4 | c.2832G>T p.K944N (on ENST00000392977 / NM_001286615.2; = p.K909N on NM_178826.4) | Missense Mutation (SNP) | VAF 87/400 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.711); catalogued as rs1213896214; called by muse, mutect2, varscan2
- ANO5 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs745972421, COSV61083410; called by muse, varscan2
- ANO8 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.726); catalogued as rs376028722; called by muse, varscan2
- ANO9 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs775520567; called by muse, mutect2, varscan2
- ANOS1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 98/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761052947, COSV99390839; called by muse, varscan2
- ANP32D | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV99874353; called by muse, mutect2, varscan2
- ANTXR1 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 87/396 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs747143387, COSV58023545; called by muse, mutect2, varscan2
- ANTXR2 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 61/529 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs757107442, COSV55018418; called by muse, mutect2, varscan2
- ANXA11 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.421); catalogued as rs142001721; called by muse, mutect2, varscan2
- ANXA11 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as rs200598844, COSV55418180; called by muse, mutect2, varscan2
- ANXA11 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs942671551; called by muse, mutect2, varscan2
- ANXA5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs141889791, COSV56638767; called by muse, mutect2
- ANXA6 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905891; called by muse, mutect2, varscan2
- AOC1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs543446294; called by muse, mutect2, varscan2
- AOC2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV53200258; called by muse, varscan2
- AOC2 | c.1814G>T p.S605I | Missense Mutation (SNP) | VAF 39/381 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53829169; called by muse, mutect2
- AOC3 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs754049376; called by muse, mutect2, varscan2
- AOPEP | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747625403, COSV52922291, COSV99469022; called by muse, mutect2, varscan2
- AOX1 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769159903, COSV101021799, COSV65979799; called by muse, mutect2, varscan2
- AOX1 | c.3217C>T p.R1073C | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs775339736, COSV53495680; called by muse, mutect2, varscan2
- AP000311.1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT deleterious, low confidence (0.05); catalogued as COSV51708737; called by muse, mutect2, varscan2
- AP000812.4 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs950057959; called by muse, mutect2, varscan2
- AP1G2 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs775546256; called by muse, mutect2, varscan2
- AP1S2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 132/587 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as rs1413131028; called by muse, mutect2, varscan2
- AP3B2 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760645573; called by muse, mutect2, varscan2
- AP3M2 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV99441710; called by mutect2, varscan2
- AP4B1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454940627; called by muse, mutect2, varscan2
- AP5B1 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1329771168, COSV57503922; called by muse, mutect2, varscan2
- AP5Z1 | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs770433979; called by muse, mutect2, varscan2
- APAF1 | c.3416G>A p.S1139N (on ENST00000551964 / NM_181861.2; = p.S1085N on NM_001160.3) | Missense Mutation (SNP) | VAF 33/345 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV100244492; called by muse, mutect2
- APAF1 | c.3551G>A p.C1184Y (on ENST00000551964 / NM_181861.2; = p.C1130Y on NM_001160.3) | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs754108532; called by muse, varscan2
- APBA1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 111/469 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as rs777319156, COSV99596041; called by muse, mutect2, varscan2
- APBB3 | c.1132G>A p.A378T (on ENST00000357560 / NM_133173.2; = p.A385T on NM_006051.3) | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs777567525, COSV100021159; called by muse, mutect2, varscan2
- APC | c.2185C>A p.L729I | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CX983260, COSV57324183; called by muse, mutect2, varscan2
- APC | c.5267C>T p.S1756F | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs773178712, COSV57372931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5758C>T p.R1920* | Nonsense Mutation (SNP) | VAF 115/509 reads (23%) | catalogued as COSV57330105; called by muse, mutect2, varscan2
- APC2 | c.6562G>A p.D2188N | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1341607645; called by muse, mutect2, varscan2
- APEH | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1019425441, COSV56534537; called by muse, mutect2, varscan2
- APEX1 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746072642; called by muse, mutect2, varscan2
- APEX2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 84/350 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs868705455, COSV58190428; called by muse, mutect2, varscan2
- APH1A | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782208863; called by muse, mutect2
- APLP1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375567499; called by muse, mutect2, varscan2
- APMAP | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1568812447; called by muse, mutect2, varscan2
- APOA4 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs754506873, COSV100759398; called by muse, mutect2, varscan2
- APOB | c.10673G>A p.R3558H | Missense Mutation (SNP) | VAF 87/396 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs762035088, COSV51930542; called by muse, mutect2, varscan2
- APOB | c.3374C>A p.S1125Y | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV51942293; called by muse, mutect2
- APOB | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs780841518, COSV51922701; called by muse, varscan2
- APOBR | c.2523G>T p.E841D (on ENST00000431282; = p.E850D on NM_018690.4) | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as COSV60491357; called by muse, mutect2, varscan2
- APOO | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 97/387 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs748097340, COSV64870302; called by muse, mutect2, varscan2
- APP | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 68/345 reads (20%) | catalogued as COSV61003344; called by mutect2, varscan2
- APPBP2 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 105/447 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.706); catalogued as rs761525267, COSV50027935; called by muse, mutect2, varscan2
- APTX | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs760391639; called by muse, mutect2, varscan2
- AR | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101018044; called by muse, mutect2, varscan2
- AR | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 103/460 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs138454018, CM064982; called by muse, mutect2, varscan2
- AR | c.2250G>T p.M750I | Missense Mutation (SNP) | VAF 93/486 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV65957144; called by muse, mutect2, varscan2
- ARAF | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV51692007; called by muse, mutect2, varscan2
- ARAP3 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.173); catalogued as rs201996634; called by muse, mutect2, varscan2
- ARC | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 72/400 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as rs1201978742; called by muse, mutect2, varscan2
- ARCN1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782522980; called by muse, mutect2, varscan2
- AREL1 | c.1771C>A p.L591M | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100707642; called by muse, mutect2, varscan2
- ARFGAP1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555818132; called by muse, mutect2, varscan2
- ARFGEF1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs200392828, COSV51620792; called by muse, mutect2, varscan2
- ARFGEF1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 49/496 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1563894275; called by muse, mutect2, varscan2
- ARFGEF2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1050725257; called by muse, mutect2, varscan2
- ARFGEF3 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs754312669; called by muse, varscan2
- ARFGEF3 | c.3923G>A p.G1308D | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as rs1364031472; called by muse, mutect2
- ARGFX | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1355116733, COSV57681470; called by muse, mutect2, varscan2
- ARGFX | c.372T>G p.V124= | Splice Region (SNP) | VAF 44/174 reads (25%) | catalogued as COSV57683637; called by muse, varscan2
- ARHGAP1 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs747965330; called by muse, mutect2, varscan2
- ARHGAP10 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs759498019, COSV60602830; called by muse, mutect2, varscan2
- ARHGAP11A | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs751204257, COSV100853315; called by muse, mutect2, varscan2
- ARHGAP15 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs779731753; called by muse, varscan2
- ARHGAP18 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1388565595; called by muse, mutect2, varscan2
- ARHGAP20 | c.3458C>A p.S1153Y | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as COSV104391025, COSV52809581; called by muse, mutect2, varscan2
- ARHGAP20 | c.1595T>G p.F532C | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV99503033; called by muse, mutect2, varscan2
- ARHGAP21 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs760349763; called by muse, mutect2, varscan2
- ARHGAP22 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 48/399 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs927039629, COSV50936342; called by muse, mutect2, varscan2
- ARHGAP23 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as rs866924997; called by muse, varscan2
- ARHGAP23 | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.153); catalogued as rs755574639; called by muse, varscan2
- ARHGAP25 | c.1835G>A p.R612H (on ENST00000409202 / NM_001007231.3; = p.R604H on NM_014882.3) | Missense Mutation (SNP) | VAF 120/448 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374053151; called by muse, mutect2, varscan2
- ARHGAP26 | c.1982A>G p.N661S | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1262925193; called by muse, mutect2, varscan2
- ARHGAP27 | c.1498G>A p.A500T (on ENST00000428638 / NM_001282290.1; = p.A159T on NM_199282.3) | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480021763; called by muse, mutect2, varscan2
- ARHGAP31 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748347343, COSV51798990; called by muse, mutect2, varscan2
- ARHGAP32 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs944275957, COSV100089211; called by muse, mutect2, varscan2
- ARHGAP33 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs780268327, COSV50139149; called by muse, varscan2
- ARHGAP33 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs537289034, COSV50156769; called by muse, mutect2, varscan2
- ARHGAP35 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 76/368 reads (21%) | catalogued as COSV68329300; called by muse, mutect2, varscan2
- ARHGAP35 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 91/373 reads (24%) | catalogued as COSV68330154; called by muse, mutect2, varscan2
- ARHGAP36 | c.1377C>T p.I459= | Splice Region (SNP) | VAF 26/354 reads (7%) | catalogued as rs1436389659, COSV52272876, COSV99357677; called by muse, mutect2
- ARHGAP4 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1228748892, COSV63133646; called by muse, mutect2, varscan2
- ARHGAP45 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs763773150; called by muse, mutect2, varscan2
- ARHGAP45 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100490626; called by muse, mutect2
- ARHGAP6 | c.1719C>A p.F573L | Missense Mutation (SNP) | VAF 126/603 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57300344; called by muse, mutect2, varscan2
- ARHGEF1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as rs371771035; called by muse, varscan2
- ARHGEF1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs918201984; called by muse, varscan2
- ARHGEF10 | c.3398G>A p.R1133H (on ENST00000398564; = p.R1108H on NM_014629.4) | Missense Mutation (SNP) | VAF 152/454 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs779333941, COSV50662954; called by muse, varscan2
- ARHGEF10L | c.3157G>A p.A1053T | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1293742992; called by muse, mutect2
- ARHGEF11 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746467759, COSV59352836; called by muse, mutect2, varscan2
- ARHGEF11 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 62/310 reads (20%) | catalogued as COSV63811869; called by muse, mutect2, varscan2
- ARHGEF11 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367970481; called by muse, mutect2, varscan2
- ARHGEF16 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs950525199; called by muse, mutect2, varscan2
- ARHGEF18 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV60468460; called by muse, mutect2, varscan2
- ARHGEF19 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 102/396 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781407343; called by muse, varscan2
- ARHGEF2 | c.2387C>T p.A796V (on ENST00000361247 / NM_001162383.2; = p.A768V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1170520147; called by muse, mutect2, varscan2
- ARHGEF25 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212907781, COSV99677718; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF26 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 106/573 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs562212403, COSV62845684; called by muse, mutect2, varscan2
- ARHGEF26 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 98/465 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377732491; called by muse, mutect2, varscan2
- ARHGEF3 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 127/458 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs759626361, COSV56324447; called by muse, mutect2, varscan2
- ARHGEF33 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV67258271; called by muse, mutect2, varscan2
- ARHGEF40 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs746319531; called by muse, mutect2, varscan2
- ARHGEF6 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51695784; called by muse, mutect2, varscan2
- ARHGEF7 | c.1021G>A p.E341K (on ENST00000375741 / NM_001113511.2; = p.E163K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs753457702; called by mutect2, varscan2
- ARHGEF7 | c.1811C>T p.P604L (on ENST00000375741 / NM_001113511.2; = p.P426L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs775468277; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 30/214 reads (14%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARID2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs1025267667; called by muse, mutect2
- ARID3A | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs751888436, COSV55043024; called by muse, varscan2
- ARID5B | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746843478, COSV54421115; called by muse, mutect2, varscan2
- ARIH1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs752084483; called by muse, varscan2
- ARL2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1427174815, COSV55860951; called by muse, mutect2, varscan2
- ARL2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs946607464; called by muse, mutect2, varscan2
- ARL8B | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747994602, COSV56578900; called by muse, varscan2
- ARMC1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as rs763773660; called by muse, mutect2, varscan2
- ARMC2 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 60/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753812764, COSV64553660; called by muse, mutect2
- ARMC4 | c.1745T>C p.V582A | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV59464070; called by muse, mutect2, varscan2
- ARMC5 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV51656694; called by muse, mutect2, varscan2
- ARMC9 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.501); catalogued as rs542598901; called by muse, mutect2, varscan2
- ARMCX6 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1351235915; called by muse, mutect2, varscan2
- ARNT2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371290912, CM141148; called by muse, varscan2
- ARPP21 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 112/548 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51804246; called by muse, mutect2
- ARPP21 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99491613; called by muse, mutect2, varscan2
- ARRDC1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765783709, COSV58378389; called by muse, mutect2, varscan2
- ARRDC1 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs974920587; called by muse, mutect2, varscan2
- ARSA | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.699); catalogued as rs369593442; called by muse, mutect2, varscan2
- ARSB | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443412816; called by muse, mutect2, varscan2
- ARSH | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs1189979750, COSV66963075; called by muse, varscan2
- ARSI | c.1235A>G p.N412S | Missense Mutation (SNP) | VAF 47/324 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs760446128; called by muse, mutect2, varscan2
- ARSI | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs199878549, COSV60817229; called by muse, mutect2, varscan2
- ARSI | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as rs778824134; called by muse, mutect2, varscan2
- ARSK | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1478829084, COSV66169781; called by muse, mutect2, varscan2
- ARSK | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs370775377; called by muse, mutect2, varscan2
- ARVCF | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1181972203; called by muse, mutect2, varscan2
- ARX | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 101/399 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs1475419182; called by muse, mutect2, varscan2
- ARX | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV100984067; called by muse, mutect2, varscan2
- ASAP2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs207461514; called by muse, mutect2, varscan2
- ASAP2 | c.2975G>A p.R992H | Missense Mutation (SNP) | VAF 113/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs781249376, COSV53005492; called by muse, mutect2, varscan2
- ASB1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs766226125, COSV99223479; called by muse, varscan2
- ASB16 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758866778; called by muse, mutect2, varscan2
- ASB18 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV58234927; called by muse, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 95/404 reads (24%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASB9 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV66852385; called by muse, mutect2
- ASB9 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.201); catalogued as COSV104431582; called by muse, mutect2, varscan2
- ASCC3 | c.5020C>T p.R1674C | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112466876, COSV100976363; called by muse, mutect2, varscan2
- ASCC3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138861677, COSV100225520; called by muse, mutect2, varscan2
- ASIP | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as rs1268280327; called by muse, mutect2, varscan2
- ASMTL | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs371220130, COSV101188029, COSV67243316; called by muse, mutect2, varscan2
- ASMTL | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 92/430 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs749599167, COSV67244646; called by muse, mutect2, varscan2
- ASNSD1 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 60/469 reads (13%) | catalogued as COSV53623071, COSV53623187; called by muse, mutect2, varscan2
- ASPDH | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1162111256; called by muse, varscan2
- ASPG | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs746427452; called by muse, mutect2, varscan2
- ASPH | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199833011; called by muse, mutect2, varscan2
- ASPH | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV62862054; called by muse, mutect2, varscan2
- ASPHD1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375732156; called by muse, varscan2
- ASPM | c.7816A>G p.T2606A | Missense Mutation (SNP) | VAF 119/541 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as CD131293; called by muse, mutect2, varscan2
- ASPM | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 38/453 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54137244; called by muse, mutect2
- ASTN2 | c.1898C>T p.A633V (on ENST00000313400 / NM_001365069.1; = p.A582V on NM_014010.5) | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs752461666, COSV57818498; called by muse, varscan2
- ASXL1 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60109907; called by muse, mutect2, varscan2
- ASXL1 | c.3602A>G p.Q1201R | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs778774838; called by muse, varscan2
- ATAD2 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 38/383 reads (10%) | catalogued as rs1309068218, COSV54881315; called by muse, mutect2
- ATAD2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 120/512 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1396494854; called by muse, mutect2, varscan2
- ATAD2B | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53205247; called by muse, mutect2, varscan2
- ATAD5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs373509661, COSV58971918; called by muse, mutect2, varscan2
- ATF1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs567759490; called by muse, mutect2, varscan2
- ATF7IP | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.046); catalogued as COSV53771820; called by muse, mutect2, varscan2
- ATG13 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 83/345 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs759630324, COSV56317809; called by muse, mutect2, varscan2
- ATG2A | c.4426C>T p.R1476W | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970063407; called by muse, mutect2
- ATG2A | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs914302325; called by muse, mutect2
- ATG2B | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 42/224 reads (19%) | catalogued as rs930827694; called by muse, varscan2
- ATG4A | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 46/634 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58964262; called by muse, mutect2
- ATL3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776571949, COSV100219637; ClinVar: likely benign; called by muse, varscan2
- ATM | c.2141C>T p.T714I | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1555074846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.862); catalogued as rs372999568; called by muse, mutect2, varscan2
- ATN1 | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1555143712; called by muse, mutect2, varscan2
- ATN1 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 47/455 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs782212323, COSV100755838; called by muse, mutect2, varscan2
- ATP10A | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs550258170, COSV63518869; called by muse, varscan2
- ATP10A | c.3276C>A p.F1092L | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV63516263, COSV63526806; called by muse, mutect2, varscan2
- ATP10A | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs143743235; called by muse, mutect2, varscan2
- ATP11B | c.3154C>A p.P1052T | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs777840897; called by muse, mutect2, varscan2
- ATP11C | c.3200T>C p.V1067A | Missense Mutation (SNP) | VAF 96/611 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.313); catalogued as rs890191882; called by muse, mutect2, varscan2
- ATP11C | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 75/461 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV59571182; called by muse, mutect2, varscan2
- ATP12A | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs7328155; called by muse, varscan2
- ATP13A1 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs758996948; called by muse, mutect2, varscan2
- ATP13A2 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs139065780; called by muse, mutect2, varscan2
- ATP13A5 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 140/477 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs776857987; called by muse, mutect2, varscan2
- ATP13A5 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 114/379 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs776380026, COSV60868282; called by muse, varscan2
- ATP1A2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV63406099; called by muse, mutect2, varscan2
- ATP2B2 | c.3124C>T p.P1042S (on ENST00000352432; = p.P1008S on NM_001683.5) | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1320953291; called by muse, mutect2, varscan2
- ATP2B3 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782696034, COSV54867238; called by muse, mutect2, varscan2
- ATP2B3 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs782655482; called by muse, varscan2
- ATP2B4 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs986432272, COSV100398125; called by muse, mutect2, varscan2
- ATP4A | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs929702152, COSV52867389; called by muse, varscan2
- ATP4A | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs908819738, COSV52871584; called by muse, mutect2, varscan2
- ATP4A | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV52867413; called by muse, mutect2
- ATP6V0A1 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1482791268; called by muse, varscan2
- ATP6V0A2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs866240852; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs756272879; called by muse, mutect2, varscan2
- ATP6V0E2 | c.134C>T p.A45V (on ENST00000425642; = p.A94V on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs201500750; called by muse, mutect2, varscan2
- ATP6V0E2 | c.163G>A p.A55T (on ENST00000425642; = p.A104T on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1282823901, COSV101374598; called by muse, mutect2
- ATP6V1D | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 33/356 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV53600265; called by muse, mutect2
- ATP7A | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 104/472 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV58445276; called by muse, mutect2, varscan2
- ATP7A | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 42/497 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100431019; called by muse, mutect2
- ATP8A2 | c.2327A>G p.E776G | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV54947774; called by muse, varscan2
- ATP8A2 | c.3272C>T p.A1091V | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.434); catalogued as rs199725711, COSV99681789; called by muse, mutect2, varscan2
- ATP8A2 | c.3467C>T p.P1156L | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.072); catalogued as COSV54940483, COSV99679679; called by muse, varscan2
- ATP8B1 | c.3596G>A p.R1199H | Missense Mutation (SNP) | VAF 81/381 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as rs543858152; called by muse, mutect2, varscan2
- ATP8B2 | c.2036C>T p.T679M (on ENST00000672630; = p.T646M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs776972025, COSV59246518; called by muse, mutect2, varscan2
- ATP8B2 | c.2228G>A p.R743Q (on ENST00000672630; = p.R710Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs769777681; called by muse, mutect2, varscan2
- ATP8B4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752810289, COSV52718864; called by muse, mutect2, varscan2
- ATP9B | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs750015330, COSV100303466; called by muse, mutect2, varscan2
- ATXN2 | c.1441C>T p.R481C (on ENST00000550104; = p.R321C on NM_002973.4) | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772885925; called by muse, mutect2, varscan2
- ATXN7 | c.2608A>G p.T870A | Missense Mutation (SNP) | VAF 31/457 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1332039591; called by muse, mutect2
- ATXN7L1 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs200750459; called by muse, mutect2, varscan2
- AUNIP | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1023572603; called by muse, mutect2, varscan2
- AURKA | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749883403, COSV57167364; called by muse, mutect2, varscan2
- AURKB | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs201709756, COSV60244668; called by mutect2, varscan2
- AVEN | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.98); catalogued as rs1167721878, COSV60733355; called by muse, mutect2, varscan2
- AWAT2 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs776219301; called by muse, mutect2, varscan2
- AXDND1 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs371568732, COSV62639980; called by muse, mutect2, varscan2
- AXDND1 | c.1926G>A p.M642I | Missense Mutation (SNP) | VAF 64/338 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62646148; called by muse, mutect2, varscan2
- AXIN1 | c.2034G>T p.Q678H | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.759); catalogued as rs1399745546; called by muse, mutect2, varscan2
- AXIN2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs730881396; ClinVar: uncertain significance; called by muse, varscan2
- AXL | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV56576729; called by muse, varscan2
- AZI2 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 102/523 reads (20%) | catalogued as rs1475381397; called by muse, mutect2, varscan2
- B3GALNT1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs765788938; called by muse, mutect2, varscan2
- B3GALT2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 132/505 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs767764174, COSV66463911; called by muse, mutect2, varscan2
- B3GALT6 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55420101; called by muse, varscan2
- B3GAT1 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100437830; called by muse, mutect2, varscan2
- B3GNT3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764743027, COSV59438389; called by muse, varscan2
- B3GNT3 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as rs748234589, COSV100427602; called by muse, varscan2
- B3GNT4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs374927709; called by muse, mutect2, varscan2
- B3GNT7 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1224722111, COSV55005728; called by muse, mutect2, varscan2
- B3GNT7 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 166/333 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs767032436; called by muse, mutect2, varscan2
- B3GNTL1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761380761, COSV57952281; called by muse, mutect2, varscan2
- B3GNTL1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769145172; called by muse, mutect2, varscan2
- B4GALNT3 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777184832; called by muse, mutect2, varscan2
- B4GALNT4 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1337433471; called by muse, mutect2
- B4GALT4 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 152/492 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs759941186, COSV63295548; called by muse, mutect2, varscan2
- B4GALT6 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371621631; called by muse, varscan2
- B4GALT6 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 71/293 reads (24%) | catalogued as rs914225321; called by muse, mutect2, varscan2
- B4GALT7 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542850594, COSV50353946; called by muse, mutect2, varscan2
- BAAT | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 124/519 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs974951490, COSV52288889; called by muse, varscan2
- BACH2 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs140270440; called by muse, varscan2
- BACH2 | c.2118C>A p.F706L | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.996); catalogued as COSV57591252; called by muse, varscan2
- BAG5 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 110/450 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370330698; called by muse, varscan2
- BAHCC1 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.127); catalogued as rs782655241; called by muse, mutect2, varscan2
- BAHCC1 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs370722185; called by muse, mutect2, varscan2
- BAHD1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs767193943, COSV69083918; called by muse, varscan2
- BAK1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775198844, COSV100645875, COSV62349705; called by muse, mutect2, varscan2
- BASP1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 39/496 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs1234911317; called by muse, mutect2
- BATF3 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 64/189 reads (34%) | catalogued as COSV54658884; called by muse, varscan2
- BAZ1B | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59993734; called by muse, mutect2, varscan2
- BAZ1B | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59991019, COSV59993745; called by muse, varscan2
- BAZ1B | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs782307839, COSV59991078, COSV59994858; called by muse, mutect2, varscan2
- BAZ2A | c.4883G>A p.G1628D | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV51636621; called by muse, mutect2, varscan2
- BAZ2B | c.3025C>T p.R1009* | Nonsense Mutation (SNP) | VAF 91/405 reads (22%) | catalogued as rs761705661; called by muse, mutect2, varscan2
- BBS7 | c.246T>G p.I82M | Missense Mutation (SNP) | VAF 140/458 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52655878, COSV52658662; called by muse, mutect2, varscan2
- BBS9 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as rs1371853094; called by muse, mutect2, varscan2
- BBS9 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs774401569, COSV99625196; called by muse, mutect2, varscan2
- BCAM | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.154); catalogued as rs934382784, COSV54300607; called by muse, varscan2
- BCAR1 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs373463514; called by muse, mutect2, varscan2
- BCCIP | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1010143629; called by muse, mutect2, varscan2
- BCHE | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 145/478 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100012005, COSV52253121; called by muse, mutect2, varscan2
- BCHE | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 115/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013028; called by muse, varscan2
- BCL10 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 59/518 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs949558985, COSV104424132; called by muse, mutect2, varscan2
- BCL11A | c.2122G>A p.D708N (on ENST00000335712 / NM_001365609.1; = p.D742N on NM_018014.4) | Missense Mutation (SNP) | VAF 94/378 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV59634758; called by muse, mutect2, varscan2
- BCL11A | c.1231G>A p.A411T (on ENST00000335712 / NM_001365609.1; = p.A445T on NM_018014.4) | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs745490013, COSV100184710, COSV59626834; called by muse, mutect2, varscan2
- BCL11A | c.965C>T p.A322V (on ENST00000335712 / NM_001365609.1; = p.A356V on NM_018014.4) | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1330472358, COSV100185119; called by muse, varscan2
- BCL11B | c.739C>T p.R247C (on ENST00000357195 / NM_001282237.2; = p.R176C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/388 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772129957, COSV100595405, COSV61738616; called by muse, varscan2
- BCL11B | c.659G>A p.S220N (on ENST00000357195 / NM_001282237.2; = p.S149N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100595254, COSV61733498; called by muse, varscan2
- BCL2L11 | c.562C>T p.R188C (on ENST00000393256 / NM_138621.5; = p.R128C on NM_006538.5) | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs765527733; called by muse, mutect2, varscan2
- BCL3 | c.723C>T p.D241= | Splice Region (SNP) | VAF 28/307 reads (9%) | catalogued as COSV51234445; called by muse, mutect2
- BCL6B | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1200044113, COSV53427749; called by muse, mutect2, varscan2
- BCL9L | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1377714172; called by muse, mutect2, varscan2
- BCLAF1 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 80/417 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62145308; called by muse, varscan2
- BCLAF1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749571754, COSV62140896, COSV62145125; called by muse, mutect2, varscan2
- BCO1 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs761882293; called by muse, mutect2, varscan2
19,397 further variants in this file (13,634 protein-altering or splice-affecting, 5,057 silent, 706 other) are not listed here.
